Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-AA6A, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-AA6A-01A (Primary Tumor).

ICD-O-3

Adenocarcinoma, intestinal
type 8144/3
Site: gastroesophageal junction
C16.D
W 3/20/14

Collect date:

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Gastroesophageal junction)

1 - "Esophageal margin":

. See exam preoperative.

2 - "Distal esophagus (distal margin thread)":

. Lack of neoplastic involvement.

3 - "Epiploon":

. Free of neoplastic compromise.

4 - "Stomach":

. Moderately differentiated adenocarcinoma, intestinal type of Lauren.

. Neoplasia measuring 4.0 cm and infiltrating to the serosa and adjacent adipose tissue.

. Perineural infiltration not detected.

. Lymphatic infiltration present.

. Spiculated growth pattern, discrete lymphocytic peritumoral infiltrate.

. Proximal surgical margin compromised (designated F1).

. Distal margin free of neoplastic compromise.

. Metastatic carcinoma in 8 of 26 identified lymph nodes (8/26).

Absence of capsular compromise.

5 - "Thoracic esophagus":

. Absence of neoplastic compromise.

. Nonspecific chronic esophagitis.

6 - "Proximal margin of esophagus":

. Absence of neoplastic involvement.

7- "Gastric fundus":

. Moderate chronic gastritis, active.

. Absence of neoplastic compromise.

PATHOLOGIC STAGING

Topography

Stomach, NOS

Morphology

Adenocarcinoma, NOS

Stage

pT4a pN3a

Criteria	W 12/23/13	Yes	No

Source: NCI Genomic Data Commons file 683783a1-9358-4434-81df-9be6095c523a (TCGA-VQ-AA6A.E828D735-A91E-4C17-B8FF-05D9E36EE8F2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).